Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4959, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4959-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4959

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: SP: Right renal mass

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV.
- THE TUMOR GREATEST DIAMETER IS 4.1 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1) The specimen is received fresh for frozen, labeled "Right renal mass (stitch marks deep margin)". It consists of a portion of renal parenchyma with attached perirenal fat, measuring 10.0 x 6.0 x 3.5 cm. The portion of renal parenchyma measures 5.0x4.0x4.0 cm. The specimen is received previously oriented with a surgical stitch at the deep margin which is inked black and sampled for intraoperative frozen section diagnosis. The remaining margin (perirenal fat margin) is inked blue. Sectioning reveals a mass that measures 4.1 x 3.9 x 3 cm and is serially sectioned to reveal a yellow to tan and hemorrhagic aspect with focal cystic dilatation. The mass appears well-circumscribed and does not appear to penetrate through the renal capsule. The mass with adjacent perirenal fat is entirely submitted. The perirenal fat is serially sectioned to reveal a lobulated and yellow cut surface. No distinctive lesions are identified in the perirenal fat. Representative sections are submitted. Photographs are taken. Tissue is submitted for TPS.

Summary of Sections:

FSC - frozen section control

TK - tumor to kidney

TF - tumor to adjacent fat

Summary of Sections:

Part 1: SP: Right renal mass

Block

Sect. Site

PCs

[page 2 of 2]
1	FSC	1
8	TF	8
9	TK	9

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM; INKED MARGIN NEGATIVE FOR TUMOR. [REDACTED]
PERMANENT DIAGNOSIS: SAME
-

Source: NCI Genomic Data Commons file 75280f42-f8f3-4020-a9d6-0e43ee3fd19a (TCGA-BP-4959.A39B0133-81F4-423C-B15D-72211C395E33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).